Somatic mutation profile of tumor specimen TCGA-EM-A2OW-01A (aliquot TCGA-EM-A2OW-01A-11D-A202-08) from TCGA case TCGA-EM-A2OW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.7 years (13,761 days).
Specimen TCGA-EM-A2OW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ad4ab6c-f509-47ba-84eb-f5e3a394d6bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2OW-10A (Blood Derived Normal), aliquot TCGA-EM-A2OW-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b1fa32c-327b-424c-b8b3-09d61ff7159f

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSHR | c.1358T>C p.M453T | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121908864, CM981962, COSV53313526; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DLC1 | c.3808A>T p.T1270S (on ENST00000276297 / NM_001348081.2; = p.T833S on NM_006094.5) | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs770652171, COSV52291697; called by muse, mutect2, varscan2
- GGA2 | c.607C>A p.H203N | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.724); catalogued as rs778809190, COSV59167505; called by muse, mutect2, varscan2
- IGSF1 | c.2291C>G p.P764R | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63836334; called by muse, mutect2
- IL23R | c.1148+1G>A p.X383_splice | Splice Site (SNP) | VAF 4/45 reads (9%) | catalogued as COSV61372988; called by muse, mutect2
- PDZRN4 | c.1850T>C p.I617T (on ENST00000402685 / NM_001164595.2; = p.I359T on NM_013377.4) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV54193293; called by muse, mutect2, varscan2
- ZNF254 | c.1701T>G p.I567M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV61641189; called by muse, mutect2, varscan2
- ZNF624 | c.973dup p.I325Nfs*9 | Frame Shift Ins (INS) | VAF 32/110 reads (29%) | called by mutect2, varscan2
- ASTN2 | c.1539C>T p.L513= (on ENST00000313400 / NM_001365069.1; = p.L462= on NM_014010.5) | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV57754117; called by muse, mutect2, varscan2
- CXXC4 | c.570G>A p.L190= | Silent (SNP) | VAF 18/393 reads (5%) | catalogued as COSV67295872; called by muse, mutect2
- FAM155A | c.399C>G p.P133= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1334604293, COSV65550569; called by muse, mutect2
- FAM207A | c.252G>A p.S84= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs200952167; called by muse, mutect2, varscan2
- TOMM40 | c.510C>T p.P170= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs536598319, COSV52976032, COSV52977590; called by muse, mutect2, varscan2
